Surgical pathology report (de-identified scan), TCGA case TCGA-95-8039, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-8039-01A (Primary Tumor).

[page 1 of 4]
Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Encounter info:

* Final Report *

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Acc #:

DOB:

Gender: M

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. 10R LYMPH NODE, EXCISION, A1FS:

- NO METASTATIC CARCINOMA IN FRAGMENTED LYMPH NODAL TISSUE.

B. LUNG, RIGHT UPPER LOBE, LOBECTOMY, B1FS:

- MODERATELY DIFFERENTIATED ADENOCARCINOMA (1.7 X 1.7 X 2.5 CM).

- NO PLEURAL INVOLVEMENT.

- COMPLETELY EXCISED.

- EMPHYSEMA.

C. 11R LYMPH NODE, EXCISION:

- NO METASTATIC CARCINOMA IN FRAGMENTED LYMPH NODAL TISSUE.

D. 4R LYMPH NODE, EXCISION:

- NO METASTATIC CARCINOMA IN FRAGMENTED LYMPH NODAL TISSUE.

E. #7 LYMPH NODE, EXCISION:

Printed by:

Printed on:

[page 2 of 4]
Anat Path Reports

* Final Report *

- NO METASTATIC CARCINOMA IN FRAGMENTED LYMPH NODAL TISSUE.

F. 9R LYMPH NODE, EXCISION:

- NO METASTATIC CARCINOMA IN FRAGMENTED LYMPH NODAL TISSUE.

Synoptic Worksheet

B. Right upper lobe:

Specimen:	Lobe(s) of lung: Right upper lobe
Procedure:	Lobectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Upper lobe
Tumor Focality:	Unifocal
Histologic Type:	Acinar adenocarcinoma
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 2.5 cm
	Additional dimension: 1.7 cm
	Additional dimension: 1.7 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not applicable
Bronchial Margin:	Uninvolved by invasive carcinoma
	Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 50 mm
	Margin closest to invasive carcinoma: Bronchial margin
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b: Tumor greater than 2 cm, but 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)

Printed by:
Printed on:

[page 3 of 4]
Anat Path Reports

* Final Report *

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of nodes examined cannot be determined
Distant Metastasis (pM): Not applicable

Clinical History

Right VATS. Right upper lobe lung CA.

Specimen(s) Received

A: 10R Lymph node
B: Right upper lobe
C: 11R Lymph node
D: 4R Lymph node
E: #7 Lymph node
F: 9R Lymph node

Gross Description

Six specimens are received, each labeled with the patient's name and medical record number.

Specimen A is received fresh for intraoperative consultation and is labeled "10R lymph node." It consists of multiple fragments of soft black tissue measuring 1.0 x 0.9 x 0.2 cm. The specimen is submitted entirely for frozen section diagnosis in cassette "A1FS."

Specimen B is received fresh for intraoperative consultation and is labeled as "right upper lobe." It consists of a lung lobe measuring 4.5 x 13.0 x 3.0 cm and weighing 141.0 grams. There is a fleshy tan mass with lobulated borders that puckers the overlying pleura (inked blue) and measures 1.7 x 1.7 x 2.5 cm. It is 5.0 cm from the bronchial margin. The surrounding parenchyma immediately adjacent to the mass is hemorrhagic. The uninvolved parenchyma is emphysematous. The bronchial margin is submitted for frozen section diagnosis in cassette "B1FS." Additional representative sections are submitted as follows.

Specimen C is received in formalin, labeled with the patient's name, medical record number and as "right #11 lymph node." The specimen consists of multiple fragments of black soft tissue measuring 1.5 x 1.4 x 0.3 cm in aggregate. The specimen is entirely submitted in cassette "C1."

Specimen D is received in formalin, labeled with the patient's name, medical record number and as "4R lymph node." The specimen consists of multiple fragments of black soft tissue measuring 1.6 x 1.3 x 0.2 cm. The specimen is entirely submitted in cassette "D1."

Specimen E is received in formalin, labeled with the patient's name, medical record number and as "#7 lymph node." The specimen consists of multiple fragments of black soft tissue measuring 1.6 x 1.4 x 0.3 cm. The specimen is submitted entirely in cassette "E1."

Specimen F is received in formalin, labeled with the patient's name, medical record number and a "#9R lymph node." The specimen consists of two fragments of black soft tissue measuring 0.5 x 0.4 x 0.1 cm. The specimen is submitted entirely in cassette "F1."

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Anat Path Reports

* Final Report *

CASSETTE SUMMARY:

B2: Bronchial edge and vascular margin, shave
B3: Mass with respect to overlying pleura
B4: Mass with respect to uninvolved parenchyma
B5: Additional representative mass
B6: Representative uninvolved parenchyma

Intraoperative Consult Diagnosis

A1FS: 10R LYMPH NODE (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

B1FS: LUNG, RIGHT UPPER LOBE (FROZEN SECTION): BRONCHIAL MARGIN NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Microscopic Description

Microscopic examination performed.

An elastic stain performed on block B3 confirms that the visceral pleura is not involved by carcinoma.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 151dcd21-c932-4168-bc9b-cfb64e2bd560 (TCGA-95-8039.2BC3D5A2-7341-44A1-A625-FBFDEF9BBA6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).